Somatic mutation profile of tumor specimen TCGA-HC-7817-01B (aliquot TCGA-HC-7817-01B-11D-A29Q-08) from TCGA case TCGA-HC-7817, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.6 years (19,207 days).
Specimen TCGA-HC-7817-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e1644c3-166f-4a3f-bf7d-25e500e9554e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7817-10A (Blood Derived Normal), aliquot TCGA-HC-7817-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a9b197c-e28c-4482-aa93-4c38edfa8c48

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as COSV64199605; called by muse, mutect2, varscan2
- DPEP1 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV104376541; called by muse, mutect2
- EP300 | c.5485C>T p.R1829C | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV54326029; called by muse, mutect2
- KLHL12 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.024); catalogued as COSV66127387; called by muse, varscan2
- KMT2C | c.6779C>G p.A2260G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs754881644, COSV51445271; called by muse, mutect2, varscan2
- LMX1B | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.88); catalogued as rs773510108, COSV62739883; called by muse, mutect2, varscan2
- OR4D10 | c.434C>G p.T145R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV73260039, COSV73260053; called by muse, mutect2, varscan2
- PNMA2 | c.59C>A p.S20* | Nonsense Mutation (SNP) | VAF 32/220 reads (15%) | catalogued as COSV72908532; called by muse, mutect2, varscan2
- SLC4A8 | c.1091T>A p.M364K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV60653183; called by muse, mutect2
- TRAJ43 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 13/110 reads (12%) | catalogued as rs370648856; called by muse, mutect2, varscan2
- TTC12 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59098073; called by muse, mutect2, varscan2
- ZNF831 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs139591279, COSV99057604; called by muse, mutect2, varscan2
- ADAMTS5 | c.1209C>T p.H403= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs774940785, COSV53176232, COSV99034717; called by muse, mutect2, varscan2
- ADCY4 | c.1845G>A p.T615= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs141339113; called by muse, mutect2, varscan2
- CKAP5 | c.2367T>G p.S789= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV56368356; called by muse, mutect2, varscan2
- EHBP1 | c.1206G>A p.P402= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as rs148159032; called by muse, mutect2, varscan2
- RSPH9 | c.471C>T p.G157= | Silent (SNP) | VAF 37/304 reads (12%) | catalogued as rs772977982, COSV64664250; called by muse, mutect2, varscan2
- THAP7 | c.363A>G p.R121= | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as COSV53147882; called by muse, mutect2, varscan2
